Gene-level copy-number profile of tumor specimen CUPP-B49F-TTM1-A from CCG case CUPP-B49F, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, malignant, uncertain whether primary or metastatic; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 76.1 years (27,793 days).
Specimen CUPP-B49F-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0c55f27a-dc46-4fd9-b36a-df142edac3b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B49F-NT1-A (ffpe scrolls); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,269 have no estimate.
https://portal.gdc.cancer.gov/files/4c51992f-1604-4a30-a44f-2bd7b9f0c82a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 31; copy number 2: 265; copy number 3: 22,747; copy number 4: 35,188; copy number 5: 69; copy number 6: 32; copy number 7: 4; copy number 8: 11; copy number 9: 4; copy number 10: 1; copy number 11: 1; copy number 28: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,269,604–145,269,890, 1 gene, copy number 28: AC245014.2.
- chr1:146,064,711–146,237,807, 3 genes, copy number 9 (within-gene range 5–9): NBPF10, NOTCH2NLA, AC239799.1.
- chr4:8,990,455–8,990,806, 1 gene, copy number 11: AC073648.2.
- chr12:118,758,217–118,761,739, 1 gene, copy number 10: LINC02423.
- chr21:13,544,210–13,545,185, 1 gene, copy number 9: OR4K11P.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
